Somatic mutation profile of tumor specimen TCGA-IQ-7632-01A (aliquot TCGA-IQ-7632-01A-11D-2078-08) from TCGA case TCGA-IQ-7632, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 68.4 years (24,986 days).
Specimen TCGA-IQ-7632-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 146b2eba-df3c-4614-975f-b6d74faf23da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IQ-7632-10A (Blood Derived Normal), aliquot TCGA-IQ-7632-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fd81e9f-3f96-48a2-99bf-6d1e6c05cde0

The open-access MAF lists 44 somatic variants for this specimen: 34 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 28, Silent 10, Nonsense Mutation 4, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG4 | c.498T>A p.N166K | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.123); catalogued as COSV99797605; called by muse, mutect2
- BAIAP3 | c.3221C>T p.T1074M | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201353225, COSV99136218; called by muse, mutect2, varscan2
- BPIFB6 | c.467T>C p.M156T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV100848570; called by muse, mutect2, varscan2
- CCDC180 | c.4017G>T p.E1339D | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as COSV100827428; called by muse, mutect2, varscan2
- CCT8L2 | c.937G>C p.V313L | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs747115852, COSV100743275, COSV63462569; called by muse, mutect2
- CNOT1 | c.3424G>C p.E1142Q | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99801705; called by muse, mutect2
- CYRIB | c.222G>C p.K74N | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV101310481; called by muse, mutect2
- EFL1 | c.2260C>T p.R754* | Nonsense Mutation (SNP) | VAF 8/96 reads (8%) | catalogued as rs1330065864; called by muse, mutect2
- FLG | c.6811G>T p.A2271S | Missense Mutation (SNP) | VAF 25/311 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100912473; called by muse, mutect2
- FLNA | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); catalogued as COSV100775426; called by muse, mutect2, varscan2
- H2BC14 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV100297701; called by muse, mutect2, varscan2
- HEY2 | c.908T>G p.I303S | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV100856448; called by muse, mutect2
- HTR1A | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100109348; called by muse, mutect2, varscan2
- KDM3B | c.1859A>G p.N620S | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100070383; called by muse, mutect2, varscan2
- KMT2D | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV99986886; called by muse, mutect2, varscan2
- LRBA | c.6307G>A p.E2103K | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs769501419, COSV58260738; ClinVar: uncertain significance; called by muse, mutect2
- P3H4 | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs371239589; called by muse, varscan2
- PCDH11X | c.1198A>G p.T400A | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100016401; called by muse, mutect2
- PCDHGB3 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54009214; called by muse, varscan2
- PCSK1 | c.1088A>T p.Q363L | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV100227343; called by muse, mutect2, varscan2
- PLK1 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 14/289 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1041097622, COSV55621786; called by muse, mutect2
- SACS | c.3169G>C p.D1057H | Missense Mutation (SNP) | VAF 5/131 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as COSV101207866; called by muse, mutect2
- SCML1 | c.533C>G p.T178S (on ENST00000380041 / NM_001037540.3; = p.T151S on NM_006746.6) | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101193999; called by muse, mutect2, varscan2
- SESN3 | c.1010A>C p.D337A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99566133; called by muse, mutect2, varscan2
- SLC38A9 | c.1662C>A p.N554K | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100591636; called by muse, mutect2, varscan2
- SMOC1 | c.491A>G p.D164G | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as rs766160933, COSV100734903; called by muse, mutect2
- ST8SIA1 | c.431G>A p.G144D | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99683759; called by muse, mutect2
- SYCP2 | c.1422A>T p.K474N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62771694; called by muse, mutect2, varscan2
- TOMM34 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs779517223, COSV65688819; called by muse, mutect2
- TRIM27 | c.1532C>G p.T511S | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.522); catalogued as COSV101019542; called by muse, mutect2, varscan2
- TRPA1 | c.2017del p.T673Hfs*23 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | catalogued as rs748693374; called by mutect2, pindel, varscan2
- TTF2 | c.1870A>T p.K624* | Nonsense Mutation (SNP) | VAF 5/66 reads (8%) | catalogued as COSV101037963; called by muse, mutect2
- VARS2 | c.1534C>T p.Q512* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100423191; called by muse, mutect2, varscan2
- ABCC3 | c.3922_3923del p.D1308Pfs*38 | Frame Shift Del (DEL) | VAF 11/92 reads (12%) | called by pindel, varscan2
- CABCOCO1 | c.267A>G p.E89= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV100358146; called by muse, mutect2, varscan2
- CCDC181 | c.720T>G p.P240= | Silent (SNP) | VAF 17/127 reads (13%) | catalogued as COSV100890417; called by muse, mutect2, varscan2
- DNAH8 | c.6696C>T p.R2232= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as COSV100547537; called by muse, mutect2, varscan2
- LDLRAD4 | c.792C>T p.G264= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs756294361, COSV100762651; called by muse, mutect2, varscan2
- SLC44A4 | c.1941G>T p.G647= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV99999428; called by muse, mutect2
- SLC4A4 | c.2568G>A p.K856= (on ENST00000264485 / NM_001098484.3; = p.K812= on NM_003759.4) | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs750632118, COSV99143769; called by mutect2, varscan2
- SRGAP2 | c.2370C>T p.V790= (on ENST00000624873 / NM_001170637.4; = p.V791= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs901050473, COSV99833433; called by muse, mutect2, varscan2
- TAF6 | c.1236G>A p.L412= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV100612910; called by muse, mutect2, varscan2
- THAP2 | c.411G>A p.R137= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100350635; called by muse, mutect2
- ZFHX3 | c.8148C>T p.C2716= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV99213732; called by muse, mutect2, varscan2
